Gene-level copy-number profile of tumor specimen TCGA-28-5204-01A from TCGA case TCGA-28-5204, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.5 years (26,490 days).
Specimen TCGA-28-5204-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.fac7db1b-ed4b-4fea-88f5-1bf67402622c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-28-5204-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/463e40ae-9bc5-4791-8cd8-004b9be0d327

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 11,939; copy number 2: 44,800; copy number 3: 13; copy number 4: 3,012; copy number 21: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-28-5204-01A-01D-1479-01): tumor purity 0.88, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,090,898–9,803,784, 3 genes: RPS26P3, RN7SL5P, AL513422.1.
- chr9:17,579,066–17,797,124, 1 gene (within-gene range 0–1): SH3GL2.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–23,438,700, 17 genes (within-gene range 0–1): AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:27,948,078–28,670,286, 1 gene (within-gene range 0–1): LINGO2.
- chr9:28,539,735–28,888,955, 4 genes: AL445526.1, KCTD10P1, MIR876, MIR873.
- chr9:29,254,075–30,832,225, 11 genes: AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2.
- chr10:119,167,720–119,597,029, 9 genes: PRDX3, GRK5, GRK5-IT1, RN7SL749P, AL583824.1, MIR4681, RGS10, AC012468.1, TIAL1.
- chr10:119,997,086–120,070,159, 2 genes: NACAP2, AL355298.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,759,348–55,255,635, 6 genes, copy number 21 (within-gene range 4–21): SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1.

Autosomal genes at a single copy (total copy number 1): 9,569. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
